MMRF case MMRF_1486 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8d167bdf-0707-462c-9b9f-f54a19b17da6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 459 days (1.3 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.4 years (20,589 days); ISS stage: III; Days to last known disease status: 459 days (1.3 years); Days to last follow up: 459 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 316 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 437 days (1.2 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 316 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 317 days; Days to treatment end: 437 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 459.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 0): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.6 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 10 µg/mL; Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 295 µmol/L; Blood Urea Nitrogen 41.4 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 7.48 mmol/L; C-Reactive Protein 0.107 mg/dL.
- Day 85 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 26.9 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 7.77 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 324 µmol/L; Blood Urea Nitrogen 31.4 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 6.66 mmol/L.
- Day 169 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.1 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 7.49 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 289 µmol/L; Blood Urea Nitrogen 21.8 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 7 g/dL; Glucose 8.31 mmol/L.
- Day 260 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.4 mg/dL; Immunoglobulin G 9.18 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 4.75 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 8.58 mmol/L.
- Day 345 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.7 mg/dL; Immunoglobulin G 8.75 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 236 µmol/L; Blood Urea Nitrogen 27.8 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 9.3 mmol/L.
- Day 429 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.9 mg/dL; Hemoglobin 7.01 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 215 µmol/L; Blood Urea Nitrogen 23.2 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 9.13 mmol/L.

Other clinical attributes
- Day -23: Weight: 103 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1486_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_1486_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
